Somatic mutation profile of tumor specimen TCGA-76-6661-01B (aliquot TCGA-76-6661-01B-11D-1845-08) from TCGA case TCGA-76-6661, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 54.7 years (19,965 days).
Specimen TCGA-76-6661-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a8d958e6-fbf9-41ef-8933-fdf71db19a0b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-76-6661-10A (Blood Derived Normal), aliquot TCGA-76-6661-10A-01D-1845-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a9c9f82a-92d3-4efb-a5ef-e5527e4bb9ed

The open-access MAF lists 53 somatic variants for this specimen: 37 protein-altering or splice-affecting, 15 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 15, Nonsense Mutation 5, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.815A>C p.H272P | Missense Mutation (SNP) | VAF 13/20 reads (65%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs1114167648, COSV64288425, COSV64299515; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS19 | c.964C>T p.R322* | Nonsense Mutation (SNP) | VAF 21/45 reads (47%) | catalogued as rs1261670879, COSV50731304; called by muse, mutect2, varscan2
- ARHGAP4 | c.1972G>A p.V658M | Missense Mutation (SNP) | VAF 21/26 reads (81%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.97); catalogued as rs782046575, COSV61685713; called by muse, mutect2, varscan2
- ATF7IP2 | c.934G>C p.E312Q | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.067); catalogued as COSV61092015; called by muse, mutect2, varscan2
- BPI | c.1376C>T p.P459L (on ENST00000262865; = p.P455L on NM_001725.3) | Missense Mutation (SNP) | VAF 25/157 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs368496977, COSV53403586, COSV99481034; called by muse, mutect2, varscan2
- CD163 | c.2376A>T p.E792D | Missense Mutation (SNP) | VAF 95/230 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63128984; called by muse, mutect2, varscan2
- CYP3A5 | c.710A>C p.N237T | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); catalogued as COSV56118280; called by muse, mutect2, varscan2
- DDX41 | c.886C>G p.L296V | Missense Mutation (SNP) | VAF 68/174 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as COSV57250606; called by muse, mutect2, varscan2
- DMRTB1 | c.802C>T p.P268S | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.118); catalogued as rs868663808, COSV65112506; called by muse, mutect2, varscan2
- FBN2 | c.3430G>T p.E1144* | Nonsense Mutation (SNP) | VAF 26/71 reads (37%) | catalogued as CM1412995, COSV52489870, COSV52518440; called by muse, mutect2, varscan2
- FZD9 | c.970G>A p.G324S | Missense Mutation (SNP) | VAF 46/130 reads (35%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); catalogued as rs782048293, COSV60669417; called by muse, mutect2, varscan2
- GRID1 | c.854T>C p.F285S | Missense Mutation (SNP) | VAF 58/88 reads (66%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV60011894; called by muse, mutect2, varscan2
- GTF3C6 | c.472G>T p.D158Y | Missense Mutation (SNP) | VAF 69/174 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV57332519; called by muse, mutect2, varscan2
- HOXC9 | c.545C>T p.P182L | Missense Mutation (SNP) | VAF 44/128 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.77); catalogued as COSV57716288; called by muse, mutect2, varscan2
- JAK3 | c.3254G>A p.R1085Q | Missense Mutation (SNP) | VAF 43/151 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV71685372; called by muse, mutect2, varscan2
- KCNA4 | c.1138G>T p.V380L | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.113); catalogued as COSV60250350; called by muse, mutect2, varscan2
- KDM5A | c.4619T>G p.L1540* | Nonsense Mutation (SNP) | VAF 56/149 reads (38%) | catalogued as COSV66990104; called by muse, mutect2, varscan2
- LRP1 | c.7012G>A p.V2338I | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.919); catalogued as rs748386088, COSV54500845; called by muse, mutect2, varscan2
- MAGEC3 | c.1079G>A p.R360H | Missense Mutation (SNP) | VAF 18/23 reads (78%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs774885969, COSV53575583; called by muse, mutect2, varscan2
- MTHFD1 | c.347A>G p.N116S | Missense Mutation (SNP) | VAF 64/185 reads (35%) | SIFT tolerated (0.3); PolyPhen benign (0.022); catalogued as rs1267246674, COSV53697393; called by muse, mutect2, varscan2
- NLRX1 | c.769G>A p.G257R | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.584); catalogued as COSV52701087; called by muse, mutect2, varscan2
- OR2T4 | c.940A>T p.T314S | Missense Mutation (SNP) | VAF 36/190 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV63543196; called by muse, mutect2, varscan2
- OXCT2 | c.1405G>A p.E469K | Missense Mutation (SNP) | VAF 40/122 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs752977074, COSV59593104; called by muse, mutect2, varscan2
- PAK4 | c.1153T>C p.Y385H | Missense Mutation (SNP) | VAF 68/216 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.386); catalogued as COSV58943491; called by muse, mutect2, varscan2
- PCDH11Y | c.1253C>T p.T418M (on ENST00000400457 / NM_032973.2; = p.T407M on NM_032971.3) | Missense Mutation (SNP) | VAF 31/44 reads (70%) | SIFT tolerated (0.11); PolyPhen benign (0.065); catalogued as COSV53072638; called by muse, mutect2, varscan2
- PCDHB5 | c.11C>T p.A4V | Missense Mutation (SNP) | VAF 33/72 reads (46%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.048); catalogued as rs1251535727, COSV50647140; called by muse, varscan2
- PIKFYVE | c.833C>T p.P278L | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.031); catalogued as COSV52236288; called by muse, mutect2, varscan2
- RIN1 | c.731G>A p.S244N | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV60925220; called by muse, mutect2, varscan2
- RIPK4 | c.1466T>A p.L489Q (on ENST00000352483; = p.L441Q on NM_020639.3) | Missense Mutation (SNP) | VAF 60/184 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV60185263; called by muse, mutect2, varscan2
- RP1L1 | c.2107C>T p.R703* | Nonsense Mutation (SNP) | VAF 18/57 reads (32%) | catalogued as rs775708703, COSV66751274; called by muse, mutect2, varscan2
- SPATC1 | c.1100G>A p.R367Q | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.792); catalogued as rs372423052; called by muse, mutect2, varscan2
- TMEM109 | c.151G>C p.V51L | Missense Mutation (SNP) | VAF 37/116 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.04); catalogued as COSV50000006; called by muse, mutect2, varscan2
- TTPAL | c.994C>T p.R332* | Nonsense Mutation (SNP) | VAF 16/53 reads (30%) | catalogued as rs1259122244, COSV52828184; called by muse, mutect2, varscan2
- UBTF | c.2042A>G p.D681G | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT tolerated (0.34); PolyPhen benign (0.029); catalogued as rs1286769360, COSV57184501; called by muse, mutect2, varscan2
- USH2A | c.11341A>G p.I3781V | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1356097751, COSV56321923; called by muse, mutect2, varscan2
- VWA3A | c.1600C>T p.R534W | Missense Mutation (SNP) | VAF 41/146 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370995399; called by muse, mutect2, varscan2
- ZNF8 | c.316G>A p.A106T | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs1289242812, COSV52186436; called by muse, mutect2, varscan2
- AADACL3 | c.369C>T p.G123= | Silent (SNP) | VAF 42/72 reads (58%) | catalogued as rs200204186; called by muse, mutect2
- ASZ1 | c.45C>T p.G15= | Silent (SNP) | VAF 19/85 reads (22%) | catalogued as COSV52910884; called by muse, mutect2, varscan2
- CREB3L3 | c.966C>T p.T322= | Silent (SNP) | VAF 24/104 reads (23%) | catalogued as rs780009776, COSV50172179; called by muse, mutect2, varscan2
- DSC2 | c.450T>G p.G150= | Silent (SNP) | VAF 25/49 reads (51%) | catalogued as COSV51860711; called by muse, mutect2, varscan2
- EPHB3 | c.1656G>A p.Q552= | Silent (SNP) | VAF 40/84 reads (48%) | catalogued as COSV57803935; called by muse, mutect2, varscan2
- HECW1 | c.174C>T p.H58= | Silent (SNP) | VAF 31/97 reads (32%) | catalogued as rs906767913, COSV67820621, COSV67827293; called by muse, mutect2, varscan2
- LIAS | c.114C>A p.L38= | Silent (SNP) | VAF 62/165 reads (38%) | catalogued as rs750439302, COSV54694578; ClinVar: likely benign; called by muse, mutect2, varscan2
- MYO1F | c.744C>T p.D248= | Silent (SNP) | VAF 43/161 reads (27%) | catalogued as rs201115094; called by muse, mutect2, varscan2
- NMBR | c.300C>T p.D100= | Silent (SNP) | VAF 16/42 reads (38%) | catalogued as COSV57800315; called by muse, mutect2, varscan2
- OR5A1 | c.546C>T p.C182= | Silent (SNP) | VAF 98/277 reads (35%) | catalogued as rs1032680539, COSV100118347, COSV57375591; called by muse, mutect2, varscan2
- PCDHA5 | c.1668C>T p.D556= | Silent (SNP) | VAF 62/172 reads (36%) | catalogued as rs1554129352, COSV65348905; called by muse, mutect2, varscan2
- PIP5KL1 | c.609C>T p.V203= | Silent (SNP) | VAF 12/45 reads (27%) | catalogued as COSV55944100; called by muse, mutect2, varscan2
- PLCG2 | c.1623G>A p.T541= | Silent (SNP) | VAF 26/59 reads (44%) | catalogued as rs772797149, COSV100842695, COSV63866977; called by muse, mutect2, varscan2
- SELE | c.882C>T p.N294= | Silent (SNP) | VAF 51/131 reads (39%) | catalogued as rs374959095; called by muse, mutect2, varscan2
- TRHDE | c.78A>G p.R26= | Silent (SNP) | VAF 8/19 reads (42%) | catalogued as COSV53830508; called by muse, mutect2, varscan2
- AGAP7P | n.2047C>A | RNA (SNP) | VAF 56/148 reads (38%) | called by muse, varscan2
